Surgical pathology report (de-identified scan), TCGA case TCGA-SB-A6J6, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Baylor College of Medicine, specimen TCGA-SB-A6J6-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Seminoma NOS

9061/3

Site B Testis NOS

C62.9

gwd 6/20/13

DATE 0

Pathology Consultation Report

Final

CASE:

ANATOMIC PATHOLOGY DIAGNOSIS:

A. Right testicle, radical orchiectomy

- Seminoma, classic type
- Size 8.0 cm
- Confined to the testis
- No rete testis or epididymis invasion identified
- No lymphovascular invasion identified
- Extensive intratubular germ cell neoplasia (ITGCN) identified
- Spermatocord margin negative for tumor

B. Left testis, biopsy

- Seminiferous tubules, no pathologic alteration
- No ITGCN or malignancy identified

PATHOLOGIST:

I have reviewed this material and confirm the report. Released by electronic signature on:

MATERIAL:

- A-Right testicle
- B-Left testicular biopsy

HISTORY:

Pre-operative Diagnosis: Testicular cancer

GROSS:

A-Received fresh labeled "right testicle" is a unilateral orchiectomy specimen (61g, testis: 6 x 4.5 x 3 cm, epididymis: 3.5 x 1 x 0.5 cm, spermatic cord: length 13 cm x diameter 1 cm).

Page 1 of 3

SURGICAL PATHOLOGY

[page 2 of 3]
DATE OF DISCHARGE:

DOCTOR:

DATE OF SERVICE

Pathology Consultation Report

Final

CASE:

The specimen is bisected in the frozen room for tissue harvesting for research purposes. The specimen itself is consequently placed in formalin and brought down to routine histology area for permanent sections.

The tunica albuginea and epididymal surface is pink-tan, smooth and glistening. The tumor does not involve the tunica albuginea. The spermatic cord is pink-purple, smooth and glistening with white tubular vas deferens. The cut surface show a diffuse tan-white firm nodule (8 x 4.5 x 3 cm) abutting the tunica albuginea. There is minimal normal testicular parenchyma surrounding the nodule. A up to 1 cm yellow, necrotic, well-circumscribed area is identified 0.2 cm from the tunica albuginea surface. No hemorrhage is seen.

Spermatic cord, vas deferens and epididymis are not grossly involved by tumor. Gross photographs are obtained.

Section Codes:

A1	vas deferens resection margin
A2	spermatic cord resection margin
A3	epididymis, normal; tumor
A4-A6	rete testis, normal; tumor
A6-A8	tumor and normal, representative
A10	normal, representative.

B-Received in Boulin's solution labeled "left testicular biopsy" is a yellow-tan tubule of the testicular parenchyma (0.6 x 0.5 x 0.5 cm). The specimen is entirely submitted in cassette B1.

MICROSCOPIC:

Multiple sections of right testicular mass show a classic seminoma with focal necrosis. No other germ cell components are identified. There are extensive ITGCN. No lymphovascular invasion is identified. The spermatic cord margin is negative for tumor.

SURGICAL PATHOLOGY

[page 3 of 3]
DATE OF DISCHARGE:

DOCTOR:

DATE OF SERVICE:

Pathology Consultation Report

Final

The left testicular biopsy shows testicular parenchyma with several seminiferous tubules. There is appropriate spermatogenesis. No ITGCN or malignancy is identified.

TUMOR SYNOPTIC REPORT AND STAGING:

Anatomic Site and Laterality:	Right testicle
Procedure Type:	Radical orchiectomy
Tumor Focality:	Focal
Tumor Size (cm):	8.0 cm
Tumor Extension (macro and micro):	Within the testis
Histologic Type:	Seminoma, classic
Margins (spermatic cord and others):	Negative
Lymphovascular Invasion:	Not identified
Primary tumor (pT):	pT1
Lymph Node (pN):	pNx
Distant Metastasis (M):	cM0
Stage Grouping:	IA
Site of Distant Metastasis:	None known

Page 3 of 3

SURGICAL PATHOLOGY

Source: NCI Genomic Data Commons file aba08745-71f2-459e-9312-59db8a7755af (TCGA-SB-A6J6.080C5215-1BCA-4F60-8124-BEB12E816514.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).